TARGET case TARGET-30-PATWGR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/241806cf-34c2-5989-b247-09b7607cd2e3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 2.8 years (1,039 days); Year of diagnosis: 2010; Days to last follow up: 2,260 days (6.2 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Percent tumor nuclei: 70.
   Treatment given: Protocol identifier: AEPI07N1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 2,260 days (6.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,260; Year of follow up: 2017.

Molecular and laboratory tests
- MYCN amplification: Amplified.

Biospecimens (2 samples)
- Sample TARGET-30-PATWGR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATWGR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2260
- Protocol: ANBL00B1, ANBL0032, AEPI07N1
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
